CCDI case PBCHHJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/1bca9162-6940-481f-94c1-b7d9f04f3539

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 20.9 years (7,643 days).

Biospecimens (3 samples)
- Sample 0DW41D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW41Y: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW42C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
